Somatic mutation profile of tumor specimen TCGA-BB-8596-01A (aliquot TCGA-BB-8596-01A-11D-2394-08) from TCGA case TCGA-BB-8596, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Hypopharynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 69.6 years (25,408 days).
Specimen TCGA-BB-8596-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c74e0657-9eaa-4726-a4e3-611b602cb460.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BB-8596-10A (Blood Derived Normal), aliquot TCGA-BB-8596-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da606708-dc4a-4474-97a9-cfe2723772b2

The open-access MAF lists 92 somatic variants for this specimen: 61 protein-altering or splice-affecting, 28 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 28, Nonsense Mutation 3, 5'Flank 1, 3'UTR 1, Splice Site 1, Splice Region 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RHOA | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 17/96 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69041792, COSV69042056; called by muse, mutect2, varscan2
- AGO4 | c.2224A>G p.I742V | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.061); catalogued as COSV100942886; called by muse, mutect2
- ALDH9A1 | c.977A>G p.D326G | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV100699288; called by muse, mutect2
- AMOTL1 | c.1341A>G p.I447M | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0.01); catalogued as rs758860394, COSV100504330; called by muse, mutect2
- ANO7 | c.2776C>T p.P926S (on ENST00000274979; = p.P872S on NM_001370694.2) | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV99238007; called by muse, mutect2, varscan2
- AOX1 | c.2746T>C p.S916P | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV101021876; called by muse, mutect2, varscan2
- APEH | c.1079A>T p.Y360F | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.167); catalogued as COSV99610703; called by muse, mutect2, varscan2
- APOL3 | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.795); catalogued as COSV100652051; called by muse, mutect2
- ARNT | c.800T>A p.M267K | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100591066; called by muse, mutect2
- BRPF3 | c.461A>G p.Y154C | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100325730; called by muse, mutect2, varscan2
- CA3 | c.703G>T p.E235* | Nonsense Mutation (SNP) | VAF 7/55 reads (13%) | catalogued as COSV99570637; called by muse, mutect2, varscan2
- CCDC91 | c.1263C>G p.F421L | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.179); catalogued as COSV100081619; called by muse, mutect2, varscan2
- CLCNKA | c.455C>G p.S152C | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV100509996, COSV58891313; called by muse, mutect2
- CLDN25 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs371445026; called by muse, mutect2
- CNGB1 | c.790G>C p.E264Q | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.063); catalogued as COSV99202305; called by muse, mutect2, varscan2
- COPS6 | c.787C>G p.L263V | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as rs1315226074, COSV100384828; called by muse, mutect2, varscan2
- DNAH8 | c.11062G>A p.G3688R | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1561888205, COSV100542620; called by muse, mutect2, varscan2
- DYNC2I1 | c.1248A>G p.I416M | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as rs1178607468, COSV101337648; called by muse, mutect2, varscan2
- DZIP3 | c.942G>C p.L314F | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.996); catalogued as COSV100847735; called by muse, mutect2, varscan2
- EGFR | c.1507G>A p.G503S | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.392); catalogued as rs760711480, COSV51804028, COSV99289667; called by muse, mutect2, varscan2
- ENPP2 | c.94C>G p.R32G | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.386); catalogued as rs138726849; called by muse, mutect2, varscan2
- FAM71B | c.611C>A p.A204E | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.28); catalogued as COSV100261816, COSV100262008; called by muse, varscan2
- FILIP1 | c.2956T>G p.F986V | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV99384475; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.500A>C p.E167A | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.756); catalogued as COSV100436274; called by muse, varscan2
- GABRR1 | c.1271T>C p.M424T | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.017); catalogued as rs760804771, COSV101033838; called by muse, mutect2, varscan2
- HOXC8 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as rs765067304, COSV99236766; called by muse, mutect2
- IHO1 | c.776G>A p.R259K | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV99606020; called by muse, mutect2, varscan2
- IKBKE | c.1064A>G p.E355G | Missense Mutation (SNP) | VAF 64/219 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100898185; called by muse, mutect2, varscan2
- KIAA0408 | c.1816G>C p.E606Q | Missense Mutation (SNP) | VAF 32/215 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.22); catalogued as COSV100846867; called by muse, mutect2, varscan2
- KRT85 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.772); catalogued as rs781497688, COSV57737852; called by muse, mutect2
- LAMA2 | c.4909G>C p.E1637Q | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs138303386, COSV101370342; called by muse, mutect2, varscan2
- LRRC23 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.309); catalogued as COSV99145159; called by muse, mutect2, varscan2
- MATR3 | c.2458C>A p.H820N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100735174; called by muse, mutect2
- MEX3D | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101183490; called by muse, mutect2, varscan2
- MUC17 | c.1371G>C p.M457I | Missense Mutation (SNP) | VAF 121/671 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100072674; called by muse, mutect2, varscan2
- MYH14 | c.3823G>C p.E1275Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99222354; called by muse, mutect2, varscan2
- NBEAL1 | c.6305C>T p.S2102F | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV101355447, COSV68917244; called by muse, mutect2, varscan2
- NDST3 | c.2257G>A p.E753K | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs775212321, COSV56628137, COSV56632105; called by muse, mutect2, varscan2
- NDUFS8 | c.246C>G p.I82M | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.872); catalogued as COSV99141800; called by muse, mutect2
- NOTCH1 | c.2842G>T p.E948* | Nonsense Mutation (SNP) | VAF 55/180 reads (31%) | catalogued as COSV53045690, COSV53058447; called by muse, mutect2, varscan2
- NUMA1 | c.2735C>G p.T912S | Missense Mutation (SNP) | VAF 123/239 reads (51%) | SIFT tolerated (0.36); PolyPhen benign (0.042); catalogued as COSV100706023; called by muse, mutect2, varscan2
- OR13C3 | c.437G>A p.G146D | Missense Mutation (SNP) | VAF 33/250 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV101053300, COSV66166122; called by muse, mutect2, varscan2
- PITPNM2 | c.1665C>T p.V555= | Splice Region (SNP) | VAF 7/90 reads (8%) | catalogued as COSV99758669; called by muse, mutect2
- PIWIL2 | c.2908C>G p.L970V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100769335, COSV100769501; called by muse, mutect2
- RDX | c.1588-1G>A p.X530_splice | Splice Site (SNP) | VAF 17/117 reads (15%) | catalogued as COSV100562864; called by muse, mutect2
- RTCA | c.656G>A p.R219K | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.017); catalogued as COSV99559735; called by muse, mutect2, varscan2
- RTEL1 | c.2370G>C p.K790N | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.459); catalogued as rs553827008, COSV100542032; called by muse, mutect2, varscan2
- RUNX2 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.563); catalogued as COSV61841919, COSV61845639; called by muse, mutect2, varscan2
- SCNN1G | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 28/306 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as COSV100264089; called by muse, mutect2
- SERPINB1 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.029); catalogued as COSV101058405; called by muse, mutect2, varscan2
- SFI1 | c.2074A>G p.K692E (on ENST00000400288 / NM_001007467.3; = p.K661E on NM_014775.4) | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV101192057; called by muse, mutect2
- SRP68 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs756006076, COSV57163731; called by muse, mutect2, varscan2
- TERF2 | c.1306C>G p.L436V | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0.026); catalogued as COSV99651414; called by muse, mutect2
- TGIF2LX | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV99383255; called by muse, mutect2
- TTN | c.42640G>A p.D14214N (on ENST00000591111; = p.D6790N on NM_003319.4) | Missense Mutation (SNP) | VAF 20/97 reads (21%) | PolyPhen benign (0.104); catalogued as COSV100604983; called by muse, mutect2, varscan2
- TTN | c.32218A>G p.K10740E (on ENST00000591111; = p.K9813E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/61 reads (11%) | PolyPhen benign (0.007); catalogued as COSV100604988; called by muse, mutect2, varscan2
- UBR4 | c.15254A>G p.K5085R | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs758113125, COSV100920672; called by muse, mutect2, varscan2
- XPNPEP3 | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 34/314 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.24); catalogued as rs377686555, COSV100782352, COSV63210071; called by muse, mutect2, varscan2
- YOD1 | c.636G>A p.W212* | Nonsense Mutation (SNP) | VAF 12/269 reads (4%) | catalogued as COSV100262970; called by muse, mutect2
- CNDP2 | c.238_242del p.I80Afs*51 | Frame Shift Del (DEL) | VAF 9/59 reads (15%) | called by mutect2, pindel, varscan2
- HNF1B | c.1291C>G p.Q431E | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- ATP13A3 | c.843A>C p.I281= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV99756743; called by muse, mutect2
- BCORL1 | c.768G>A p.P256= | Silent (SNP) | VAF 26/274 reads (9%) | catalogued as rs942394147, COSV54397273; called by muse, mutect2
- BUB1 | c.1005G>C p.L335= | Silent (SNP) | VAF 15/140 reads (11%) | catalogued as COSV100241016, COSV100241140; called by muse, mutect2, varscan2
- C6 | c.1752G>T p.S584= | Silent (SNP) | VAF 38/111 reads (34%) | catalogued as COSV54706740, COSV54719134; called by muse, mutect2, varscan2
- CCDC146 | c.384C>G p.L128= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as COSV99592446; called by muse, mutect2, varscan2
- DHX40 | c.21C>G p.V7= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV99232869; called by muse, mutect2, varscan2
- DHX57 | c.4140G>A p.V1380= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as rs1165486064, COSV99769339; called by muse, mutect2
- GTF2E2 | c.289C>T p.L97= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV100577093, COSV63478141, COSV63478849; called by muse, mutect2, varscan2
- IHO1 | c.621G>A p.K207= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV99606014, COSV99606426; called by muse, mutect2, varscan2
- INF2 | c.1710G>A p.Q570= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV99383728; called by muse, mutect2, varscan2
- KANSL1L | c.1482C>T p.S494= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as COSV99910397; called by muse, mutect2, varscan2
- KRT32 | c.1290C>G p.V430= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV99862970, COSV99863189; called by muse, mutect2, varscan2
- LARGE1 | c.1989G>C p.V663= | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as COSV100505099; called by muse, mutect2, varscan2
- LILRB5 | c.1608C>T p.D536= (on ENST00000449561 / NM_001081442.3; = p.D535= on NM_006840.5) | Silent (SNP) | VAF 65/227 reads (29%) | catalogued as rs753258465, COSV100300248; called by muse, mutect2, varscan2
- MAGEE2 | c.1137C>A p.L379= | Silent (SNP) | VAF 32/159 reads (20%) | catalogued as COSV64897955; called by muse, mutect2, varscan2
- MGA | c.5496G>A p.R1832= (on ENST00000219905 / NM_001164273.1; = p.R1623= on NM_001080541.2) | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV99579427; called by muse, mutect2, varscan2
- MGA | c.5973G>A p.K1991= (on ENST00000219905 / NM_001164273.1; = p.K1782= on NM_001080541.2) | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as rs1168826573, COSV99579430; called by muse, mutect2, varscan2
- NTRK3 | c.2112C>G p.V704= | Silent (SNP) | VAF 23/134 reads (17%) | catalogued as COSV100712610; called by muse, mutect2, varscan2
- OR2B3 | c.420C>T p.F140= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV101013774; called by muse, mutect2, varscan2
- OR2M4 | c.690T>C p.S230= | Silent (SNP) | VAF 22/114 reads (19%) | catalogued as COSV100141104; called by muse, mutect2, varscan2
- OR4K5 | c.717G>T p.T239= | Silent (SNP) | VAF 27/187 reads (14%) | catalogued as rs137857056, COSV100262301; called by muse, mutect2, varscan2
- OR5M3 | c.549C>T p.I183= | Silent (SNP) | VAF 10/202 reads (5%) | catalogued as COSV100392435; called by muse, mutect2
- P2RY8 | c.1050C>T p.P350= | Silent (SNP) | VAF 18/115 reads (16%) | catalogued as rs1289493642, COSV101183978; called by muse, mutect2, varscan2
- TNR | c.1626C>T p.G542= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as rs746000237, COSV54893161; called by muse, mutect2, varscan2
- TTN | c.55929T>C p.T18643= (on ENST00000591111; = p.T11219= on NM_003319.4) | Silent (SNP) | VAF 18/113 reads (16%) | catalogued as COSV100604982; called by muse, mutect2, varscan2
- TYSND1 | c.1269C>A p.I423= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs1337933831, COSV99751852; called by muse, mutect2, varscan2
- USE1 | c.345G>A p.A115= | Silent (SNP) | VAF 25/96 reads (26%) | catalogued as rs201300912, COSV55728725; called by muse, mutect2, varscan2
- VRK2 | c.849C>T p.S283= | Silent (SNP) | VAF 23/159 reads (14%) | catalogued as rs1214250928, COSV100417777; called by muse, mutect2, varscan2
- EXOC3 | chr5:442588 G>C | 5'Flank (SNP) | VAF 59/243 reads (24%) | called by muse, mutect2, varscan2
- MARVELD3 | chr16:71640808 G>C | 3'Flank (SNP) | VAF 9/92 reads (10%) | catalogued as COSV99194812; called by muse, mutect2, varscan2
- PWWP2B | c.*26G>A | 3'UTR (SNP) | VAF 78/487 reads (16%) | catalogued as rs757688889, COSV59450974; called by muse, mutect2, varscan2
